Somatic mutation profile of tumor specimen 0DV995 from CCDI case PBCLYL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.7 years (639 days).
Specimen 0DV995: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d59fbca3-35dd-497f-832c-ad28ede402ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV98P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a6e226a-142d-4a85-883b-3d56b97aec54

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL5 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as rs760330533; called by muse, mutect2, varscan2
- CDH1 | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273354402, COSV55729310; called by muse, mutect2
- MAP2K7 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 124/194 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769642939, COSV67607958; called by muse, mutect2, varscan2
- PLEC | c.5659C>T p.R1887W (on ENST00000322810 / NM_201380.4; = p.R1777W on NM_000445.5) | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs782410213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPRR1A | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as rs1387473574, COSV61081761; called by muse, mutect2
- KRT38 | c.1186C>G p.R396G | Missense Mutation (SNP) | VAF 52/445 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- SMARCA4 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF652 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD52 | c.571C>T p.L191= | Silent (SNP) | VAF 23/478 reads (5%) | called by muse, mutect2
- AICDA | c.427+79G>A | Intron (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
